Somatic mutation profile of tumor specimen TCGA-DD-AAW2-01A (aliquot TCGA-DD-AAW2-01A-11D-A40P-10) from TCGA case TCGA-DD-AAW2, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 69.6 years (25,420 days).
Specimen TCGA-DD-AAW2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c192ad4-973f-41d6-ae37-32df0d679467.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAW2-10A (Blood Derived Normal), aliquot TCGA-DD-AAW2-10A-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8aae5499-8485-4862-9bcd-2c77cfec0805

The open-access MAF lists 126 somatic variants for this specimen: 100 protein-altering or splice-affecting, 26 silent.
By variant classification: Missense Mutation 84, Silent 26, Frame Shift Del 5, Splice Site 4, Nonsense Mutation 4, Frame Shift Ins 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE2 | c.583+2T>C p.X195_splice | Splice Site (SNP) | VAF 106/117 reads (91%) | catalogued as COSV99382881; called by muse, mutect2, varscan2
- ACKR3 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99799625; called by muse, mutect2, varscan2
- AIRE | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99381207; called by muse, mutect2, varscan2
- ALB | c.526C>G p.P176A | Missense Mutation (SNP) | VAF 98/226 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99891623; called by muse, mutect2, varscan2
- ALDH1L1 | c.1993A>T p.S665C | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99856990; called by muse, mutect2, varscan2
- ANAPC1 | c.1873A>G p.I625V | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100594824; called by muse, mutect2, varscan2
- ASAP3 | c.1265A>T p.H422L | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100369486; called by muse, mutect2, varscan2
- ATP12A | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); catalogued as COSV99517823; called by muse, mutect2
- C12orf43 | c.203A>T p.E68V | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.9); catalogued as COSV99990005; called by muse, mutect2, varscan2
- CACNA1B | c.5593A>G p.K1865E | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99498022; called by muse, mutect2, varscan2
- CATSPER1 | c.1369G>T p.V457F | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1458412608, COSV100376016; called by muse, mutect2, varscan2
- CCDC80 | c.1421G>T p.G474V | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as COSV99244884; called by muse, mutect2, varscan2
- CHD1 | c.1880A>G p.Y627C | Missense Mutation (SNP) | VAF 28/474 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99399542; called by muse, mutect2
- CNGB3 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 167/236 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as COSV100182188; called by muse, mutect2, varscan2
- COBL | c.3368A>G p.K1123R | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.096); catalogued as COSV99472908; called by muse, mutect2, varscan2
- COL6A3 | c.6027C>A p.N2009K | Missense Mutation (SNP) | VAF 119/287 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV99799004; called by muse, mutect2, varscan2
- CRTC3 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99185695; called by muse, mutect2, varscan2
- DCDC1 | c.2721T>G p.F907L (on ENST00000597505 / NM_001367979.1; = p.F14L on NM_020869.3) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV100338392; called by muse, mutect2, varscan2
- DCST1 | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as rs772085683, COSV99793304; called by muse, mutect2, varscan2
- DDX1 | c.247A>C p.T83P | Missense Mutation (SNP) | VAF 76/203 reads (37%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.679); catalogued as COSV99246414; called by muse, mutect2, varscan2
- DOP1A | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 61/82 reads (74%) | SIFT tolerated (0.96); PolyPhen benign (0.017); catalogued as COSV99382171; called by muse, mutect2, varscan2
- DTNA | c.1218T>G p.H406Q | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99313312; called by muse, mutect2, varscan2
- DUOX2 | c.332A>G p.H111R | Missense Mutation (SNP) | VAF 85/183 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV100545876; called by muse, mutect2, varscan2
- DYNC2H1 | c.10903A>G p.S3635G | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1427787839, COSV100518788; called by muse, mutect2, varscan2
- EPS8L2 | c.769-2A>T p.X257_splice | Splice Site (SNP) | VAF 117/240 reads (49%) | catalogued as rs111293076, COSV100585584; called by muse, mutect2
- FA2H | c.755T>A p.L252Q | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99547791; called by muse, mutect2, varscan2
- FAM171B | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 101/202 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775021880, COSV100488689; called by muse, mutect2, varscan2
- FAT1 | c.11347A>C p.K3783Q | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV101499410; called by muse, mutect2, varscan2
- FOXK2 | c.870A>C p.K290N | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100082184; called by muse, mutect2, varscan2
- FRMPD1 | c.327A>C p.E109D | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.121); catalogued as COSV100733567; called by muse, mutect2, varscan2
- GNL3 | c.591A>C p.K197N | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV99803880; called by muse, mutect2, varscan2
- H2AC8 | c.194A>T p.E65V | Missense Mutation (SNP) | VAF 288/377 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99773270; called by muse, mutect2, varscan2
- HIF3A | c.719C>A p.A240D (on ENST00000377670 / NM_152795.4; = p.A171D on NM_022462.4) | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV99355849; called by mutect2, varscan2
- IGKV2D-24 | c.144C>A p.S48R | Missense Mutation (SNP) | VAF 146/374 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs929661480; called by muse, varscan2
- INTS3 | c.2244+2T>A p.X748_splice | Splice Site (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100016173; called by muse, mutect2, varscan2
- ITPR1 | c.4756C>A p.R1586S (on ENST00000354582; = p.R1571S on NM_002222.7) | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.285); catalogued as COSV100231723; called by muse, mutect2, varscan2
- KDM5C | c.2017A>G p.M673V | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100949263; called by muse, mutect2
- KLHL1 | c.1800C>A p.G600= | Splice Region (SNP) | VAF 32/49 reads (65%) | catalogued as COSV100917485; called by muse, mutect2, varscan2
- KNSTRN | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 41/102 reads (40%) | catalogued as COSV99991894; called by muse, mutect2, varscan2
- LAMC2 | c.589C>A p.R197S | Missense Mutation (SNP) | VAF 83/303 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs184817147, COSV99917555; called by muse, mutect2, varscan2
- LEP | c.143C>T p.T48M | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.05); catalogued as rs770247453, COSV100451429; called by muse, varscan2
- LRIG3 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as rs1454191094, COSV57865247; called by muse, mutect2, varscan2
- LYRM4 | c.232A>G p.T78A | Missense Mutation (SNP) | VAF 52/384 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1237012996, COSV100403721; called by muse, mutect2, varscan2
- MAGI2 | c.2729G>C p.G910A | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.294); catalogued as COSV100834912; called by muse, mutect2, varscan2
- MKI67 | c.651A>T p.E217D | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV100896657; called by muse, mutect2, varscan2
- MKNK1 | c.7A>C p.S3R | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as COSV100361321; called by muse, mutect2, varscan2
- MLF2 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 22/48 reads (46%) | catalogued as COSV99180094; called by muse, mutect2, varscan2
- MLF2 | c.271-1G>C p.X91_splice | Splice Site (SNP) | VAF 21/48 reads (44%) | catalogued as COSV99180095; called by muse, mutect2, varscan2
- MLLT1 | c.1493A>G p.E498G | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV99398066; called by muse, mutect2, varscan2
- MMP21 | c.1388T>C p.I463T | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as COSV100523569; called by muse, mutect2, varscan2
- MSH6 | c.2173A>G p.I725V | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs148898662; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- MUC16 | c.8777C>T p.S2926F | Missense Mutation (SNP) | VAF 90/195 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as COSV101199992, COSV101200187; called by muse, mutect2, varscan2
- MYOZ2 | c.301T>A p.S101T | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.113); catalogued as COSV100201731, COSV61085155; called by muse, mutect2, varscan2
- NAIP | c.98A>T p.Q33L | Missense Mutation (SNP) | VAF 88/148 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV99519324; called by muse, mutect2, varscan2
- NCAM1 | c.2359C>A p.P787T (on ENST00000316851 / NM_181351.5; = p.P777T on NM_000615.7) | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV100377916; called by muse, mutect2, varscan2
- NKX2-5 | c.155A>T p.K52M | Missense Mutation (SNP) | VAF 124/208 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV100234848; called by muse, mutect2, varscan2
- NOS3 | c.720C>A p.D240E | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99871777; called by muse, mutect2, varscan2
- NQO1 | c.127T>G p.Y43D | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100276647; called by muse, mutect2, varscan2
- OR5M11 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 64/132 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV101602048, COSV73141630; called by muse, mutect2, varscan2
- OR9G1 | c.176A>G p.Y59C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752912640, COSV100380446; called by muse, mutect2, varscan2
- PAN2 | c.1325A>T p.Y442F | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99228331; called by muse, mutect2, varscan2
- PCDHB3 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); catalogued as rs782520817, COSV99165459; called by muse, mutect2, varscan2
- PDE1B | c.1294A>T p.T432S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.639); catalogued as COSV99226417; called by muse, mutect2, varscan2
- PDGFRA | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99956813; called by muse, mutect2
- PDPR | c.2533G>A p.A845T | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199510800; called by muse, mutect2, varscan2
- PICALM | c.756A>C p.K252N | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV100707916; called by muse, mutect2, varscan2
- PIWIL3 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.254); catalogued as COSV100177713; called by muse, mutect2, varscan2
- PRLR | c.77T>C p.L26S | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99184472; called by muse, mutect2, varscan2
- RIOK3 | c.827A>G p.E276G | Missense Mutation (SNP) | VAF 125/282 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1200931755, COSV100259350; called by muse, mutect2, varscan2
- RTN1 | c.593A>T p.D198V | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50718848, COSV99955912; called by muse, mutect2, varscan2
- SAMD9 | c.704T>C p.I235T | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101180288; called by muse, mutect2, varscan2
- SHC1 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 191/314 reads (61%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV100460454; called by muse, varscan2
- SLC5A9 | c.1925A>G p.K642R | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99361750; called by muse, mutect2, varscan2
- SPEM1 | c.370T>A p.C124S | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100081095; called by muse, mutect2, varscan2
- SPG11 | c.5227A>G p.I1743V | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1419267108, COSV99968892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPNS1 | c.10T>C p.S4P | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.91); catalogued as COSV100209115; called by muse, mutect2, varscan2
- TAB1 | c.890A>T p.E297V | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99336105; called by muse, mutect2, varscan2
- TANGO6 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99936376; called by muse, mutect2, varscan2
- TBCE | c.1085A>G p.Y362C (on ENST00000366601; = p.Y425C on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64005058; called by muse, mutect2, varscan2
- TCHH | c.5339G>T p.R1780L | Missense Mutation (SNP) | VAF 72/115 reads (63%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs199599922, COSV100915174, COSV64273456; called by muse, mutect2, varscan2
- TJP1 | c.3679A>G p.I1227V | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV100632793; called by muse, mutect2, varscan2
- TMEM115 | c.398T>G p.V133G | Missense Mutation (SNP) | VAF 129/216 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV99223520; called by muse, mutect2, varscan2
- TRPC7 | c.803T>G p.M268R | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV100725765; called by muse, mutect2
- TTBK1 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 52/313 reads (17%) | catalogued as COSV52489945; called by muse, mutect2, varscan2
- TTN | c.6953G>A p.R2318H (on ENST00000591111; = p.R2272H on NM_003319.4) | Missense Mutation (SNP) | VAF 64/125 reads (51%) | PolyPhen probably damaging (0.998); catalogued as rs761566436, COSV60182770; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGT1A1 | c.725T>A p.V242E | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100530372; called by muse, mutect2, varscan2
- UHRF1 | c.2T>C p.M1? (on ENST00000612630 / NM_001290050.1; = p.M14T on NM_013282.4) | Translation Start Site (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV99503557; called by muse, mutect2, varscan2
- WDR1 | c.1562G>T p.G521V (on ENST00000382452; = p.G381V on NM_005112.5) | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.243); catalogued as COSV101221121; called by muse, mutect2, varscan2
- WNT5B | c.757G>C p.A253P | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV100148721; called by muse, mutect2, varscan2
- ZAN | c.5470C>A p.P1824T | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100769833; called by muse, mutect2, varscan2
- ZDHHC8 | c.2251A>T p.K751* | Nonsense Mutation (SNP) | VAF 43/110 reads (39%) | catalogued as COSV100272936; called by muse, mutect2, varscan2
- ZNF181 | c.581A>G p.K194R | Missense Mutation (SNP) | VAF 188/404 reads (47%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); catalogued as COSV101106295; called by muse, mutect2, varscan2
- ZNRF4 | c.1136A>T p.H379L | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as COSV55776416, COSV99706576; called by muse, mutect2, varscan2
- DDX60L | c.1005del p.W335Cfs*7 | Frame Shift Del (DEL) | VAF 156/346 reads (45%) | called by mutect2, pindel*, varscan2
- FBXL18 | c.1295_1304del p.A432Gfs*45 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- IGKV2D-24 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 148/378 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.205); called by muse, varscan2
- MYO16 | c.2309del p.Q770Rfs*28 | Frame Shift Del (DEL) | VAF 33/92 reads (36%) | called by mutect2, pindel, varscan2
- NCKAP1L | c.1919_1925del p.K640Rfs*40 | Frame Shift Del (DEL) | VAF 84/219 reads (38%) | called by mutect2, pindel, varscan2
- USP37 | c.2405dup p.M802Ifs*4 | Frame Shift Ins (INS) | VAF 21/64 reads (33%) | called by mutect2, pindel, varscan2
- ZNF276 | c.1202_1206del p.A401Efs*3 (on ENST00000443381 / NM_001113525.2; = p.A326Efs*3 on NM_152287.4) | Frame Shift Del (DEL) | VAF 86/226 reads (38%) | called by mutect2, varscan2
- ADAM15 | c.9G>T p.L3= | Silent (SNP) | VAF 47/92 reads (51%) | catalogued as COSV99665064; called by muse, mutect2, varscan2
- ADAMTS9 | c.2526A>C p.T842= | Silent (SNP) | VAF 52/129 reads (40%) | catalogued as COSV99899624; called by muse, mutect2, varscan2
- APBA2 | c.183G>A p.Q61= | Silent (SNP) | VAF 103/210 reads (49%) | catalogued as COSV101382293; called by muse, mutect2, varscan2
- CDK13 | c.3954A>G p.E1318= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as COSV99475670; called by muse, mutect2, varscan2
- CRIM1 | c.2289A>T p.A763= | Silent (SNP) | VAF 82/199 reads (41%) | catalogued as COSV99753601; called by muse, mutect2, varscan2
- DHRS9 | c.771G>T p.V257= | Silent (SNP) | VAF 123/313 reads (39%) | catalogued as COSV100513548; called by muse, mutect2, varscan2
- DYNC2H1 | c.3711T>A p.A1237= | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as COSV100518787; called by muse, mutect2, varscan2
- DYNC2I1 | c.2319G>T p.T773= | Silent (SNP) | VAF 73/240 reads (30%) | catalogued as COSV101337698; called by muse, mutect2, varscan2
- EMB | c.663G>A p.K221= | Silent (SNP) | VAF 72/250 reads (29%) | catalogued as COSV100296887; called by muse, mutect2, varscan2
- EME1 | c.1500T>C p.V500= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV99869628; called by muse, mutect2, varscan2
- FAM133B | c.100C>T p.L34= | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as COSV70075835; called by muse, mutect2, varscan2
- FBP1 | c.717T>A p.A239= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV100941250; called by muse, mutect2, varscan2
- GOLGA5 | c.2010C>T p.Y670= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs150818578, COSV99371014; called by muse, mutect2, varscan2
- GRIN2C | c.3336G>C p.S1112= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV99501094; called by muse, mutect2, varscan2
- IFIH1 | c.1101G>T p.L367= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV99718679; called by muse, mutect2, varscan2
- LZTFL1 | c.564A>G p.A188= | Silent (SNP) | VAF 37/141 reads (26%) | catalogued as COSV99944830; called by muse, mutect2, varscan2
- MMS19 | c.2643T>C p.H881= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as COSV100512909; called by muse, mutect2, varscan2
- MOB3C | c.462C>A p.I154= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV99596346; called by muse, mutect2, varscan2
- NOP56 | c.417G>A p.L139= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs140571524, COSV100250170; called by muse, mutect2, varscan2
- PLAAT5 | c.171T>C p.L57= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100080519; called by muse, mutect2, varscan2
- RAPGEF5 | c.1356G>A p.S452= (on ENST00000401957 / NM_001367602.2; = p.S755= on NM_012294.5) | Silent (SNP) | VAF 108/412 reads (26%) | catalogued as rs764071785, COSV59787904; called by muse, mutect2, varscan2
- RXFP2 | c.513T>C p.N171= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as COSV100034386; called by muse, mutect2, varscan2
- STX18 | c.735A>G p.E245= | Silent (SNP) | VAF 4/93 reads (4%) | catalogued as COSV100086219; called by muse, mutect2
- TXNDC2 | c.279A>C p.S93= (on ENST00000306084 / NM_001098529.2; = p.S26= on NM_032243.6) | Silent (SNP) | VAF 12/162 reads (7%) | catalogued as COSV100046265; called by muse, mutect2
- UGT1A1 | c.726G>C p.V242= | Silent (SNP) | VAF 60/153 reads (39%) | catalogued as COSV100530373; called by muse, mutect2, varscan2
- USH2A | c.9021C>T p.N3007= | Silent (SNP) | VAF 72/243 reads (30%) | catalogued as rs1327521692, COSV100236836, COSV56337378; called by muse, mutect2, varscan2
